Gene-level copy-number profile of tumor specimen TCGA-02-0104-01A from TCGA case TCGA-02-0104, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 29.3 years (10,699 days).
Specimen TCGA-02-0104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.8554f841-bd36-441b-8968-19d22400d6b3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0104-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ab4d769-b06e-4b5c-bdee-4e1d65d15a42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 6,291; copy number 2: 51,234; copy number 3: 1,148; copy number 4: 1,095.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0104-01): tumor purity 0.88, ploidy 1.95, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–197,341, 4 genes (within-gene range 0–1): LINC01986, AC066595.1, CHL1-AS2, AC066595.2.
- chr9:14,475–465,259, 11 genes (within-gene range 0–1): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1.
- chr9:21,994,139–24,905,735, 26 genes: CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,291. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
